Gene-level copy-number profile of tumor specimen TCGA-L7-A6VZ-01A from TCGA case TCGA-L7-A6VZ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 62.2 years (22,730 days).
Specimen TCGA-L7-A6VZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.d0fb1c07-1e8a-49d0-9290-e263a28c8356.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L7-A6VZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS.
https://portal.gdc.cancer.gov/files/cb40abf8-37c9-4115-bcbd-0f6eb672a89a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 102; copy number 1: 423; copy number 2: 10,023; copy number 3: 20,025; copy number 4: 19,094; copy number 5: 4,366; copy number 6: 1,714; copy number 7: 2,447; copy number 8: 560; copy number 9: 150; copy number 10: 8; copy number 11: 332; copy number 12: 119; copy number 13: 37; copy number 14: 156; copy number 15: 21; copy number 16: 18; copy number 18: 22; copy number 21: 19; copy number 32: 22; copy number 34: 11; copy number 37: 69; copy number 41: 20; copy number 48: 20; copy number 61: 28.

Homozygous deletions (total copy number 0; autosomes only): 96 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:245,673,732–245,676,478, 1 gene: AC104462.1.
- chr1:246,025,897–246,035,603, 1 gene: AC118555.1.
- chr13:50,519,364–50,910,764, 3 genes (within-gene range 0–2): DLEU7, RNA5SP28, RNASEH2B-AS1.
- chr13:100,464,440–100,481,205, 1 gene: PCCA-AS1.
- chr16:34,962,970–35,912,516, 81 genes (broad region; genes not listed).
- chr16:78,495,926–78,796,362, 5 genes: AC046158.1, AC046158.4, AC046158.2, AC046158.3, AC009141.1.
- chr20:14,884,250–15,022,958, 4 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,059 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:23,102,680–53,924,125, 1,097 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr7:86,216,785–105,530,671, 432 genes, copy number 7 (broad region; genes not listed).
- chr8:4,317,388–8,244,865, 140 genes, copy number 12–15 (broad region; genes not listed).
- chr8:10,606,349–12,665,588, 91 genes, copy number 32–37 (within-gene range 3–37) (broad region; genes not listed).
- chr8:27,633,868–43,674,591, 335 genes, copy number 9–41 (within-gene range 3–41) (broad region; genes not listed).
- chr8:110,334,743–122,127,184, 93 genes, copy number 7 (broad region; genes not listed).
- chr9:73,042,745–94,511,614, 332 genes, copy number 11 (within-gene range 2–11) (broad region; genes not listed).
- chr12:24,566,964–34,249,958, 214 genes, copy number 7–61 (broad region; genes not listed).
- chr16:24,537,693–30,989,147, 280 genes, copy number 8–13 (within-gene range 6–13) (broad region; genes not listed).
- chr18:28,638,714–37,236,242, 122 genes, copy number 7 (broad region; genes not listed).
- chr18:37,243,776–37,247,506, 1 gene, copy number 7: AC015961.2.
- chr19:32,978,592–33,130,542, 4 genes, copy number 7 (within-gene range 4–7): RHPN2, AC008521.1, AC008521.2, GPATCH1.
- chr20:28,563,850–64,313,132, 918 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 423. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
